Somatic mutation profile of tumor specimen TARGET-10-PARDFH-09A (aliquot TARGET-10-PARDFH-09A-01D) from TARGET case TARGET-10-PARDFH, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: female; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 4.2 years (1,518 days).
Specimen TARGET-10-PARDFH-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 33a94416-c991-47bb-84a5-ac1d60d84a49.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PARDFH-10A (Blood Derived Normal), aliquot TARGET-10-PARDFH-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/09ec5ac5-c438-4c8a-86dc-fc698eceb2c4

The open-access MAF lists 27 somatic variants for this specimen: 18 protein-altering or splice-affecting, 7 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 12, Silent 7, Splice Site 4, Nonsense Mutation 1, Splice Region 1, RNA 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BPIFB3 | c.194G>A p.R65Q | Missense Mutation (SNP) | VAF 9/27 reads (33%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1176017097, COSV64957272; called by muse, mutect2, varscan2
- CFH | c.2956+1G>T p.X986_splice | Splice Site (SNP) | VAF 4/88 reads (5%) | catalogued as CS100541, COSV100809347; called by muse, mutect2
- CSMD2 | c.2633G>A p.R878H | Missense Mutation (SNP) | VAF 53/127 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1361537418; called by muse, mutect2, varscan2
- GPR119 | c.265G>A p.A89T | Missense Mutation (SNP) | VAF 22/119 reads (18%) | SIFT tolerated (0.5); PolyPhen benign (0.024); catalogued as rs373455769; called by muse, mutect2, varscan2
- ITPR2 | c.7727C>T p.T2576M | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1305642891, COSV67266490; called by muse, mutect2, varscan2
- JAKMIP1 | c.2147G>A p.R716Q | Missense Mutation (SNP) | VAF 30/77 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV68953702, COSV68956807; called by muse, mutect2, varscan2
- LMO2 | c.241C>T p.R81W (on ENST00000395833 / NM_001142315.2; = p.R150W on NM_005574.4) | Missense Mutation (SNP) | VAF 16/29 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs145191677; called by muse, mutect2, varscan2
- MICAL2 | c.2914A>C p.N972H | Missense Mutation (SNP) | VAF 12/96 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.025); catalogued as rs1264655214, COSV56323280; called by muse, mutect2
- MOV10L1 | c.3133C>T p.R1045C | Missense Mutation (SNP) | VAF 22/57 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV53176733; called by muse, mutect2, varscan2
- ROBO1 | c.918-8G>T | Splice Region (SNP) | VAF 16/152 reads (11%) | catalogued as rs892349302; called by muse, mutect2, varscan2
- SETD1A | c.4609C>T p.R1537W | Missense Mutation (SNP) | VAF 28/67 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1390964282; called by muse, mutect2, varscan2
- ST3GAL6 | c.913G>A p.A305T | Missense Mutation (SNP) | VAF 4/37 reads (11%) | SIFT tolerated (0.23); PolyPhen benign (0.061); catalogued as rs140152670; called by mutect2, varscan2
- CDH9 | c.1391-1G>C p.X464_splice | Splice Site (SNP) | VAF 8/119 reads (7%) | called by muse, mutect2
- CSMD3 | c.9579A>C p.Q3193H (on ENST00000297405 / NM_001363185.1; = p.Q3024H on NM_052900.3) | Missense Mutation (SNP) | VAF 53/131 reads (40%) | SIFT tolerated (0.35); PolyPhen benign (0.029); called by muse, mutect2, varscan2
- NPRL2 | c.435C>A p.C145* | Nonsense Mutation (SNP) | VAF 35/125 reads (28%) | called by muse, mutect2, varscan2
- SVOPL | c.1468-1G>C p.X490_splice (on ENST00000419765; = p.X338_splice on NM_174959.3 and 1 other RefSeq transcript) | Splice Site (SNP) | VAF 29/64 reads (45%) | called by muse, mutect2, varscan2
- SVOPL | c.1468-2A>C p.X490_splice (on ENST00000419765; = p.X338_splice on NM_174959.3 and 1 other RefSeq transcript) | Splice Site (SNP) | VAF 29/64 reads (45%) | called by muse, mutect2, varscan2
- ZNF345 | c.73G>C p.E25Q | Missense Mutation (SNP) | VAF 29/155 reads (19%) | SIFT tolerated (0.08); PolyPhen benign (0.065); called by muse, mutect2, varscan2
- ABCC12 | c.570G>A p.T190= | Silent (SNP) | VAF 26/61 reads (43%) | catalogued as rs1338044933; called by muse, mutect2, varscan2
- DLGAP1 | c.186C>T p.S62= | Silent (SNP) | VAF 6/60 reads (10%) | catalogued as rs886110395, COSV100227377; called by muse, mutect2
- FAM32A | c.189G>T p.A63= | Silent (SNP) | VAF 26/85 reads (31%) | called by muse, mutect2, varscan2
- PP2D1 | c.711T>A p.S237= | Silent (SNP) | VAF 70/169 reads (41%) | called by muse, mutect2, varscan2
- SIM1 | c.2040G>A p.S680= | Silent (SNP) | VAF 45/102 reads (44%) | catalogued as rs777908185, COSV53489426; called by muse, mutect2, varscan2
- TEX13B | c.171C>T p.S57= | Silent (SNP) | VAF 5/45 reads (11%) | catalogued as rs1180503214, COSV57203242; called by muse, mutect2, varscan2
- TEX15 | c.498A>G p.S166= (on ENST00000256246; = p.S549= on NM_001350162.2) | Silent (SNP) | VAF 13/250 reads (5%) | called by muse, mutect2
- B3GALT5-AS1 | n.552C>T | RNA (SNP) | VAF 26/71 reads (37%) | called by muse, mutect2, varscan2
- MAGEE2 | c.*72G>C | 3'UTR (SNP) | VAF 10/24 reads (42%) | catalogued as COSV64897430; called by muse, mutect2, varscan2
